CCDI case PBCLCZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Gliomas; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/e5111cb6-29f4-44f6-98ac-c21fb6a51b40

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Glioma, malignant: ICD-O-3 morphology code: 9380/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 10.0 years (3,653 days).

Biospecimens (1 sample)
- Sample 0DUJ48: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
